CCDI case PBCISE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/caec9219-55ce-42bb-8e13-c3980c5e86f1

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ganglioneuroma: ICD-O-3 morphology code: 9490/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,015 days).

Biospecimens (3 samples)
- Sample 0DT1ZX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT20K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT20Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
